TARGET case TARGET-30-PARUXY — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f73bb1f-d2ea-5104-a2a4-1eb40e94863b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 2,523 days (6.9 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C72.0; Tissue or organ of origin: Spinal cord; Classification of tumor: primary; Age at diagnosis: 4.8 years (1,767 days); Year of diagnosis: 2008; Days to last follow up: 2,523 days (6.9 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Percent tumor nuclei: 30.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0421.

Follow-up (1 entry)
- Days to follow up: 2,523 days (6.9 years); Days to first event: 2,523 days (6.9 years); First event: Death; Year of follow up: 2015.

Biospecimens (2 samples)
- Sample TARGET-30-PARUXY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARUXY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2523
- Protocol: ANBL00B1, ANBL0421
- ICDO Description: Spinal cord Cervical cord Conus medullaris Filum terminale Lumbar cord Sacral cord Thoracic cord
- Percent Tumor v/s Stroma: 30/70
